Somatic mutation profile of tumor specimen TCGA-EJ-5518-01A (aliquot TCGA-EJ-5518-01A-01D-1576-08) from TCGA case TCGA-EJ-5518, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.6 years (24,313 days).
Specimen TCGA-EJ-5518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9489b3d2-0acf-4532-b17c-7131278c1295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5518-10A (Blood Derived Normal), aliquot TCGA-EJ-5518-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3a98d1f-f59e-46f4-ac59-f946bcd37447

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 4, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as rs782297535, COSV52471284; called by muse, mutect2
- ATM | c.5807T>C p.L1936S | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53766606; called by muse, mutect2, varscan2
- BABAM2 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 82/371 reads (22%) | catalogued as rs752630548, COSV56223704; called by muse, mutect2, varscan2
- CEP170 | c.3356C>A p.A1119D | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60510461, COSV60513110; called by muse, mutect2, varscan2
- DMXL2 | c.8011-2A>G p.X2671_splice | Splice Site (SNP) | VAF 33/118 reads (28%) | catalogued as COSV51853698; called by muse, mutect2
- DNMT3A | c.1320G>A p.W440* | Nonsense Mutation (SNP) | VAF 71/250 reads (28%) | catalogued as rs866490834, COSV53049674; called by muse, mutect2, varscan2
- EML5 | c.2213T>C p.L738S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.742); catalogued as COSV61350833; called by muse, mutect2, varscan2
- FAM124A | c.748G>C p.V250L (on ENST00000322475 / NM_001242312.2; = p.V286L on NM_145019.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV54479363; called by muse, mutect2, varscan2
- GRID2 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1445827888, COSV56202763; called by muse, mutect2, varscan2
- HOXB13 | c.652A>G p.K218E | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51704966; called by muse, mutect2, varscan2
- HRNR | c.2849G>A p.G950D | Missense Mutation (SNP) | VAF 284/576 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.202); catalogued as rs755677565, COSV64261713; called by muse, mutect2, varscan2
- IFIT1 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65661709; called by muse, mutect2, varscan2
- ISCU | c.187C>A p.L63M (on ENST00000311893 / NM_213595.4; = p.L38M on NM_014301.4) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.654); catalogued as COSV57209999; called by muse, mutect2, varscan2
- LRRC17 | c.465G>C p.L155F | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50867278; called by muse, mutect2, varscan2
- LRRC49 | c.1682T>C p.I561T | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV53014365; called by muse, mutect2, varscan2
- MYH7 | c.4822C>T p.R1608C | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746571601, COSV62519786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUMB | c.1778A>C p.D593A (on ENST00000355058; = p.D582A on NM_003744.5) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV53722160; called by muse, mutect2, varscan2
- OR13C5 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV101053124; called by muse, mutect2, varscan2
- OTOGL | c.5882C>G p.P1961R (on ENST00000547103; = p.P1952R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.26); catalogued as COSV54021783; called by muse, mutect2, varscan2
- PRKAG3 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 45/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761641320, COSV52103379; called by muse, mutect2, varscan2
- RASGRF2 | c.3508A>C p.N1170H | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV54137069; called by muse, mutect2
- S100A7L2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs781614358, COSV64195523; called by muse, mutect2
- UACA | c.2521A>G p.I841V | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59858623; called by muse, mutect2, varscan2
- USP28 | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 5/138 reads (4%) | catalogued as COSV50155660; called by muse, mutect2
- WDFY3 | c.9763C>T p.P3255S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV55711285; called by muse, mutect2, varscan2
- ZNF492 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as rs767049072, COSV101514032, COSV71762303; called by muse, mutect2, varscan2
- CDKN1B | c.221dup p.Y74* | Nonsense Mutation (INS) | VAF 41/95 reads (43%) | called by mutect2, pindel, varscan2
- SCAMP1 | c.852+1del p.X284_splice | Splice Site (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel
- ABCA13 | c.5784C>T p.V1928= | Silent (SNP) | VAF 96/366 reads (26%) | catalogued as COSV70041228; called by muse, mutect2, varscan2
- ATXN3L | c.789G>A p.S263= | Silent (SNP) | VAF 222/434 reads (51%) | catalogued as rs756656277, COSV66076137; called by muse, mutect2, varscan2
- BCL6 | c.147C>T p.V49= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as COSV51654919; called by muse, mutect2
- CDH13 | c.285C>T p.F95= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs770842301, COSV51810897; called by muse, mutect2, varscan2
- DCLK3 | c.1263C>T p.Y421= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs747084479, COSV69362814; called by muse, mutect2, varscan2
- LRRC7 | c.2268T>C p.H756= (on ENST00000651989 / NM_001370785.2; = p.H723= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/207 reads (4%) | catalogued as COSV50568335; called by muse, mutect2
- SEC14L1 | c.1557C>G p.L519= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV66724656; called by muse, mutect2, varscan2
- SUPV3L1 | c.231C>T p.D77= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV62846108; called by muse, mutect2, varscan2
- TMEM51 | c.555C>T p.N185= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs369757007; called by muse, mutect2, varscan2
